HCMI case HCM-WCMC-0753-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/57c28338-4fbb-47ab-94a0-c9988a650cda

Demographics
Sex at birth: female; Year of birth: 1966; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 53.2 years (19,444 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Sites of involvement: Cervix / Uterus.
   Pathology details: Lymph node involvement: Negative; Lymphatic invasion present: No; Tumor largest dimension diameter: 4.1 cm; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 36 days; Days to treatment end: 71 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,303 days (3.6 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 696.

Molecular and laboratory tests
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 78.7 kg; Height: 152.4 cm; BMI: 34.
- Timepoint category: Prior to Diagnosis; Risk factors: Adenomyosis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0753-C54-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0753-C54-01A-S2-HE: Section location: Bottom; Percent tumor cells: 22; Percent tumor nuclei: 90; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 74; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-0753-C54-01A-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 1; Percent necrosis: 6; Percent stromal cells: 13; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-WCMC-0753-C54-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0753-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 14.
